Somatic mutation profile of tumor specimen 0DIYSF from CCDI case PBBVDV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,205 days).
Specimen 0DIYSF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b753bc1e-8c59-4a16-a91f-a93d54376a5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIYS3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/251d7d0b-9a25-4488-95af-435a59df19ef

The open-access MAF lists 23 somatic variants for this specimen: 11 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 9, 3'UTR 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/751 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 277/801 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 189/1102 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 194/645 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 52/1030 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs376725292; ClinVar: benign; called by muse, mutect2
- ACOT11 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 115/496 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs765942343; called by muse, mutect2, varscan2
- C5orf22 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 141/946 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1451480178, COSV57600564; called by muse, mutect2, varscan2
- CD1C | c.329-1G>T p.X110_splice | Splice Site (SNP) | VAF 363/1475 reads (25%) | catalogued as COSV100939449; called by muse, mutect2, varscan2
- CLOCK | c.1889G>A p.S630N | Missense Mutation (SNP) | VAF 46/1489 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- MORF4L2 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 209/998 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SLC22A4 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 305/690 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- API5 | c.1320A>G p.T440= | Silent (SNP) | VAF 124/637 reads (19%) | catalogued as rs777641935; called by muse, mutect2, varscan2
- CEP112 | c.2565T>C p.D855= (on ENST00000392769 / NM_001353127.1; = p.D111= on NM_001037325.3) | Silent (SNP) | VAF 241/1129 reads (21%) | catalogued as rs1168463333; called by muse, mutect2, varscan2
- CRYBA2 | c.354C>A p.G118= | Silent (SNP) | VAF 187/794 reads (24%) | called by muse, mutect2, varscan2
- ECHDC3 | c.336G>A p.L112= | Silent (SNP) | VAF 325/594 reads (55%) | called by muse, mutect2, varscan2
- GABRQ | c.858G>A p.S286= | Silent (SNP) | VAF 185/1250 reads (15%) | catalogued as rs1556820012; called by muse, mutect2, varscan2
- GATB | c.354G>C p.A118= | Silent (SNP) | VAF 69/546 reads (13%) | called by muse, mutect2, varscan2
- OR7D2 | c.546G>A p.T182= | Silent (SNP) | VAF 117/660 reads (18%) | catalogued as rs1159005248, COSV100713027, COSV60140106; called by muse, mutect2, varscan2
- OTUD5 | c.141C>T p.G47= | Silent (SNP) | VAF 102/416 reads (25%) | catalogued as rs1334794433; called by muse, varscan2
- PCDHAC2 | c.900G>A p.T300= | Silent (SNP) | VAF 264/931 reads (28%) | called by muse, mutect2, varscan2
- FCHSD1 | c.*2098dup | 3'UTR (INS) | VAF 24/150 reads (16%) | called by mutect2, varscan2
- TBX1 | c.1009+958T>A | Intron (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- USF2 | c.*26G>A | 3'UTR (SNP) | VAF 124/255 reads (49%) | catalogued as rs573164342, COSV99723168; called by muse, mutect2, varscan2
